Somatic mutation profile of tumor specimen MMRF_1598_1_BM_CD138pos (aliquot MMRF_1598_1_BM_CD138pos_T1_KHS5U_K14088) from MMRF case MMRF_1598, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.9 years (25,157 days).
Specimen MMRF_1598_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfa6d577-6d6e-4cf5-bddc-0db25eb873d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1598_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1598_1_PB_CD3pos_C2_KHS5U_K14069; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ffdb79a-7702-4686-a8e6-5bdede49768a

The open-access MAF lists 36 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 15, Missense Mutation 12, Silent 3, Nonsense Mutation 2, 5'Flank 1, In Frame Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.4189C>T p.R1397C | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs145667385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GNT3 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 6/166 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1253293467, COSV59437261, COSV59438678; called by muse, mutect2
- KDF1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs377413091; called by muse, mutect2, varscan2
- LAMB2 | c.5204G>A p.R1735Q | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.205); catalogued as COSV104399260; called by muse, mutect2, varscan2
- LRP8 | c.898C>T p.R300C | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs894113689; called by muse, mutect2, varscan2
- PARD3B | c.3199G>T p.D1067Y (on ENST00000406610 / NM_001302769.2; = p.D998Y on NM_057177.7) | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.879); catalogued as COSV62513236; called by muse, mutect2
- PDE3A | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV62968477; called by muse, mutect2, varscan2
- DEF6 | c.1022C>T p.A341V | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- FNDC3A | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 58/70 reads (83%) | called by mutect2, varscan2
- KAT6B | c.6006G>A p.M2002I | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); called by muse, mutect2, varscan2
- MYO7A | c.1408T>C p.F470L | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- N4BP1 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- NCOR2 | c.4682C>T p.T1561I | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); called by mutect2, varscan2
- PPP1R18 | c.364delinsAGGG p.R122_R123insG | In Frame Ins (INS) | VAF 56/163 reads (34%) | called by pindel, varscan2*
- VSIG10L | c.883G>A p.V295M | Missense Mutation (SNP) | VAF 6/139 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- IMP3 | c.48G>C p.V16= | Silent (SNP) | VAF 20/38 reads (53%) | called by muse, mutect2, varscan2
- MICAL2 | c.36G>A p.A12= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs142020972, COSV99816489; called by muse, mutect2, varscan2
- MINDY1 | c.603G>A p.L201= | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as COSV56499565; called by muse, mutect2, varscan2
- ABL2 | c.*3915G>C | 3'UTR (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100772919; called by muse, mutect2
- AGBL4 | c.*477A>T | 3'UTR (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- DIPK2B | c.*556G>A | 3'UTR (SNP) | VAF 27/74 reads (36%) | catalogued as rs756847025, COSV67641402; called by muse, mutect2, varscan2
- DYNC1LI2 | c.*935G>A | 3'UTR (SNP) | VAF 34/78 reads (44%) | called by muse, mutect2, varscan2
- LCP2 | c.*1059C>T | 3'UTR (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- MPPED2 | c.*944G>A | 3'UTR (SNP) | VAF 16/38 reads (42%) | called by muse, varscan2
- MYLIP | c.*1061_*1062del | 3'UTR (DEL) | VAF 23/62 reads (37%) | called by mutect2, pindel, varscan2
- NDUFA5 | c.*2078del | 3'UTR (DEL) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- PLN | c.*532G>A | 3'UTR (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- PRKCE | c.*2967dup | 3'UTR (INS) | VAF 29/62 reads (47%) | catalogued as rs1031230282; called by mutect2, varscan2
- RPIA | c.*759C>G | 3'UTR (SNP) | VAF 33/104 reads (32%) | called by muse, mutect2, varscan2
- SEMA3A | c.*1218T>A | 3'UTR (SNP) | VAF 28/50 reads (56%) | called by muse, mutect2, varscan2
- SPATA31C2 | n.3741C>T | RNA (SNP) | VAF 10/18 reads (56%) | catalogued as rs1473348045; called by mutect2, varscan2
- SULT1B1 | c.*19C>G | 3'UTR (SNP) | VAF 8/159 reads (5%) | called by muse, mutect2
- TAPT1 | chr4:16227147 G>A | 5'Flank (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- TAS2R30 | c.*130_*131del | 3'UTR (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- USP22 | c.945-142T>G | Intron (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- ZFP91 | c.*2037A>C | 3'UTR (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
